TCGA case TCGA-CV-A468 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Lip; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c801a6b-8407-46da-b6cc-245f05418b9e

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 42 years; Vital status: Dead; Days to death: 464 days (1.3 years).

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C00.9; Tissue or organ of origin: Lip, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 42.1 years (15,372 days); Year of diagnosis: 2001; AJCC staging edition: 5th; AJCC clinical T: T3; AJCC clinical N: N2b; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T4a; AJCC pathologic N: N2a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 2; Lymph nodes tested: 34; Margin status: Uninvolved; Perineural invasion present: Yes.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 26 days; Days to treatment end: 67 days; Treatment dose: 42 Gy; Treatment outcome: Complete Response; Number of fractions: 14; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 26 days; Days to treatment end: 67 days; Treatment dose: 50 Gy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 26 days; Days to treatment end: 67 days; Treatment dose: 42 Gy; Treatment outcome: Complete Response; Number of fractions: 21; Treatment anatomic sites: Primary Tumor Field.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 464 days (1.3 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 25; Tobacco smoking onset year: 1977.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-A468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 220 mg.
  Slide TCGA-CV-A468-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 75; Percent normal cells: 20; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CV-A468-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-A468-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Anatomic organ subdivision: Lip; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 2; Alcohol history documented: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 464 days; disease-specific survival: no event (censored), 464 days; progression-free interval: no event (censored), 464 days.
